Somatic mutation profile of tumor specimen TCGA-RY-A843-01A (aliquot TCGA-RY-A843-01A-11D-A36O-08) from TCGA case TCGA-RY-A843, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.3 years (11,083 days).
Specimen TCGA-RY-A843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79a6d0b1-4441-4b63-ae79-0e67ab7cdc6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A843-10A (Blood Derived Normal), aliquot TCGA-RY-A843-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b2a34d5-5a42-4d64-9c84-ff3f379351f3

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ASAP1 | c.2429C>G p.P810R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as rs773610272, COSV100727441; called by muse, mutect2, varscan2
- DDX42 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834966; called by muse, mutect2, varscan2
- FOXA2 | c.512C>T p.A171V (on ENST00000377115 / NM_153675.3; = p.A177V on NM_021784.5) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101008405; called by muse, mutect2, varscan2
- GGPS1 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV99270509; called by muse, mutect2, varscan2
- INPP5B | c.956A>G p.Q319R (on ENST00000373023; = p.Q239R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as COSV100886531; called by muse, mutect2, varscan2
- KMT2B | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385766471, COSV55859337; called by muse, mutect2
- KNDC1 | c.1512C>T p.N504= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as rs755288859, COSV58839894; called by muse, mutect2, varscan2
- OCRL | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853847, CM983298, COSV100843479; ClinVar: not provided; called by muse, mutect2, varscan2
- PITX1 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV99530668; called by muse, mutect2, varscan2
- TMEM74 | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99865738; called by muse, mutect2, varscan2
- TMPRSS15 | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1233258902, COSV99518318; called by muse, mutect2, varscan2
- UTP25 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV101504749; called by muse, mutect2, varscan2
- VPS18 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV99592542; called by muse, mutect2, varscan2
- ZMIZ1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV57892061; called by muse, mutect2, varscan2
- SENP6 | c.2462dup p.P822Afs*4 | Frame Shift Ins (INS) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- TACC3 | c.2492T>C p.L831P | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CALHM1 | c.771C>T p.D257= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99588691; called by muse, mutect2
- LAMC3 | c.3444G>A p.Q1148= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs771746595, COSV100736020; called by muse, mutect2, varscan2
- RBPMS | c.168G>A p.K56= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99824131; called by muse, mutect2, varscan2
- RSPH14 | c.639G>A p.A213= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs769662275, COSV99320920; called by muse, varscan2
- ZNF565 | c.379C>T p.L127= (on ENST00000355114; = p.L87= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100411918; called by muse, mutect2, varscan2
